CCDI case PBBVRS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a52ff5f2-7bd6-4ecf-bf9c-fc5f6643d12c

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: ICD-O-3 morphology code: 9473/3; Tissue or organ of origin: Cerebrum; Age at diagnosis: 2.5 years (930 days).

Biospecimens (3 samples)
- Sample 0DIMVT: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIMWO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIMX3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
